Somatic mutation profile of tumor specimen TCGA-D5-5539-01A (aliquot TCGA-D5-5539-01A-01D-1650-10) from TCGA case TCGA-D5-5539, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.5 years (22,097 days).
Specimen TCGA-D5-5539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da32a30-1bf1-4c22-8b46-20ec8ae33a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-5539-10A (Blood Derived Normal), aliquot TCGA-D5-5539-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6944274d-a853-4e41-8b99-0810f4d76199

The open-access MAF lists 111 somatic variants for this specimen: 74 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 33, Nonsense Mutation 8, RNA 3, Frame Shift Ins 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 113/287 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53127430; called by muse, mutect2, varscan2
- ADAM7 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51545752; called by muse, mutect2, varscan2
- ADAMTS12 | c.1644G>T p.W548C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61276367; called by muse, mutect2, varscan2
- ADAMTSL3 | c.26G>A p.W9* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV54459324; called by muse, mutect2, varscan2
- ANKRD26 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV65798253; called by muse, mutect2, varscan2
- ANPEP | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201704361; called by muse, varscan2
- ASAP1 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100727978; called by muse, mutect2, varscan2
- CACNA1I | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs775512120, COSV60817053; called by muse, mutect2, varscan2
- CNTNAP3 | c.1563C>G p.D521E | Missense Mutation (SNP) | VAF 86/1010 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV52674235; called by muse, mutect2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR2 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV59281505, COSV59281842; called by muse, mutect2
- DCBLD2 | c.2279C>G p.S760* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV54584384; called by muse, mutect2, varscan2
- DDX58 | c.2698G>A p.G900R | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV59384174; called by muse, mutect2, varscan2
- DENND4B | c.4135G>A p.V1379I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs1458222424, COSV63411532; called by muse, mutect2, varscan2
- DLGAP2 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as rs370260485; called by muse, mutect2, varscan2
- DPRX | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs752125092, COSV64949935; called by muse, mutect2, varscan2
- FAM98C | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV53039659; called by muse, mutect2, varscan2
- FZD9 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554563556, COSV60671256; called by muse, mutect2, varscan2
- GGA1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs11543985, COSV57331557; called by muse, mutect2, varscan2
- HDAC5 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs775168585, COSV56820892, COSV99871129; called by muse, mutect2, varscan2
- HHIPL2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs753340048, COSV58567177; called by muse, mutect2, varscan2
- IFNG | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99971313; called by muse, mutect2, varscan2
- IGSF9 | c.1451G>A p.W484* (on ENST00000368094 / NM_001135050.2; = p.W468* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as rs1452120092, COSV63642039; called by muse, mutect2, varscan2
- INSR | c.2447C>T p.T816M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1242001529, COSV57171878; called by muse, mutect2, varscan2
- ISYNA1 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs368064258; called by mutect2, varscan2
- KIR3DL3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767458176, COSV99400127; called by muse, varscan2
- MACROD2 | c.1117T>C p.S373P (on ENST00000642719; = p.S345P on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54042760; called by muse, mutect2, varscan2
- MAG | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV62700344; called by muse, mutect2, varscan2
- MASP2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.084); catalogued as COSV53570593; called by muse, mutect2, varscan2
- MGRN1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99274963; called by muse, mutect2
- MKRN3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs745694373, COSV58808917; called by muse, mutect2, varscan2
- MMP13 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52825407; called by muse, mutect2, varscan2
- MYO18B | c.7576A>G p.S2526G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV59137949; called by muse, varscan2
- NFATC2IP | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1183587573, COSV57911237; called by muse, mutect2, varscan2
- NT5DC3 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1250899746, COSV67322698; called by muse, mutect2, varscan2
- NYAP2 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV56000867, COSV56010633; called by muse, mutect2, varscan2
- NYAP2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.225); catalogued as COSV56015052, COSV99796348; called by muse, mutect2, varscan2
- OBSCN | c.7147C>T p.R2383W | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1239653998, COSV52751297; called by muse, mutect2, varscan2
- OBSCN | c.9743C>T p.P3248L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.82); catalogued as rs772338853, COSV99475833; called by muse, mutect2, varscan2
- OR10A6 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV59165009, COSV59165908; called by muse, mutect2, varscan2
- OR14I1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs375187596; called by muse, mutect2, varscan2
- P2RY2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV60776496, COSV60776837; called by muse, mutect2, varscan2
- PCLO | c.12743dup p.N4248Kfs*31 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs1423947853; called by mutect2, pindel, varscan2
- PCLO | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 359/984 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs547726879, COSV61660879; called by muse, mutect2, varscan2
- PIAS3 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.98); catalogued as rs148589543; called by muse, mutect2, varscan2
- PIWIL1 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as COSV55351163; called by muse, mutect2, varscan2
- PTEN | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 194/348 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1114167654, COSV64288532, COSV64295272; ClinVar: uncertain significance; called by muse, mutect2
- PTK7 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140848241; called by muse, mutect2, varscan2
- PTPRT | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as rs773152433, COSV61959419, COSV61981777; called by muse, mutect2, varscan2
- PTPRT | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.116); catalogued as COSV62012725; called by muse, mutect2, varscan2
- RUNX1T1 | c.163A>T p.T55S (on ENST00000265814 / NM_001198628.1; = p.T28S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/360 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV56160876; called by muse, mutect2, varscan2
- SCN9A | c.4057A>G p.T1353A (on ENST00000303354; = p.T1342A on NM_002977.3) | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV57618891; called by muse, mutect2
- SEMG2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs144655663; called by muse, mutect2, varscan2
- SORCS3 | c.1505T>A p.F502Y | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV63822050; called by muse, mutect2, varscan2
- SPG11 | c.2311_2312insG p.F771Cfs*4 | Frame Shift Ins (INS) | VAF 40/238 reads (17%) | catalogued as COSV56001199; called by mutect2, pindel, varscan2
- SRRM2 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs140913607; called by muse, mutect2, varscan2
- TEKT5 | c.37T>A p.C13S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs755511541, COSV99296461; called by muse, varscan2
- TNXB | c.4574G>A p.R1525H (on ENST00000647633; = p.R1278H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs368042869; called by muse, mutect2, varscan2
- TRPM3 | c.3647C>G p.S1216* (on ENST00000357533 / NM_001366142.2; = p.S1071* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 82/130 reads (63%) | catalogued as COSV62593404; called by muse, mutect2, varscan2
- TRPV3 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as rs1490859805, COSV56790283; called by muse, mutect2, varscan2
- TSHZ3 | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99552947; called by muse, mutect2, varscan2
- TTN | c.14174C>T p.T4725M (on ENST00000591111; = p.T3798M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | PolyPhen benign (0.001); catalogued as rs1060500462, COSV59993962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNL4B | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV51700565; called by muse, mutect2, varscan2
- UBN2 | c.1646A>G p.N549S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.846); catalogued as rs371325900; called by muse, mutect2, varscan2
- USH2A | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs138739049; called by muse, mutect2, varscan2
- VPS33B | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs754113358, COSV60979282; called by muse, mutect2, varscan2
- ZC3H13 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768273440, COSV54451024; called by muse, mutect2, varscan2
- ZNF205 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs553960419, COSV99530665; called by muse, mutect2, varscan2
- ZNF248 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as COSV100627762; called by muse, mutect2
- ZNF423 | c.362C>T p.A121V (on ENST00000563137 / NM_001379286.1; = p.A113V on NM_015069.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs377052758, COSV52202753; ClinVar: uncertain significance; called by mutect2, varscan2
- ZNF829 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs371617827, COSV66986874; called by muse, mutect2, varscan2
- ZNF84 | c.2047T>C p.Y683H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- AMPD1 | c.361C>T p.L121= | Silent (SNP) | VAF 121/315 reads (38%) | catalogued as COSV100815331, COSV62418337; called by muse, mutect2, varscan2
- CARS1 | c.1656C>G p.T552= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV53460059; called by muse, mutect2
- CCDC88C | c.1383G>A p.A461= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs753079228, COSV66241133; called by muse, mutect2, varscan2
- CEP170 | c.216G>A p.R72= | Silent (SNP) | VAF 56/775 reads (7%) | catalogued as COSV100839652, COSV100839904; called by muse, mutect2
- CHMP7 | c.162C>T p.G54= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- CMTR2 | c.1296A>G p.K432= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV57604848; called by muse, mutect2, varscan2
- CNTN5 | c.741C>A p.I247= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV54312240, COSV99681963; called by muse, mutect2, varscan2
- CRP | c.99G>A p.S33= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as rs1309388012, COSV54813343; called by muse, mutect2, varscan2
- DNAH17 | c.11124C>T p.D3708= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs763823748, COSV67759144, COSV67760318; called by muse, mutect2, varscan2
- DNAJC4 | c.384C>T p.N128= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs372252507; called by muse, mutect2, varscan2
- FAT4 | c.849G>A p.A283= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV67896329; called by muse, mutect2, varscan2
- GAMT | c.465C>T p.H155= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1454250040, COSV52041050; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFI35 | c.525G>T p.L175= (on ENST00000415816 / NM_001330230.2; = p.L177= on NM_005533.5) | Silent (SNP) | VAF 55/174 reads (32%) | catalogued as COSV55896909; called by muse, mutect2, varscan2
- IGF2R | c.4806C>T p.S1602= | Silent (SNP) | VAF 105/280 reads (38%) | catalogued as rs771243457, COSV100808286; called by muse, varscan2
- LILRB3 | c.1821C>T p.Y607= (on ENST00000346401; = p.Y595= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/207 reads (34%) | catalogued as rs965758371, COSV54445559; called by muse, mutect2, varscan2
- MFSD9 | c.369T>C p.Y123= | Silent (SNP) | VAF 78/186 reads (42%) | catalogued as COSV51495432; called by muse, varscan2
- MUC4 | c.15603C>A p.T5201= (on ENST00000463781 / NM_018406.7; = p.T965= on NM_004532.6) | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as COSV57800504; called by muse, mutect2, varscan2
- NTM | c.504T>G p.T168= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV66186346, COSV66191564; called by muse, mutect2
- OR10G4 | c.618C>T p.A206= | Silent (SNP) | VAF 74/439 reads (17%) | catalogued as COSV57978445; called by muse, mutect2, varscan2
- OR5AP2 | c.366C>T p.A122= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV57258660; called by muse, mutect2, varscan2
- PIK3CG | c.816G>A p.L272= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100783243; called by muse, mutect2, varscan2
- PRPS1L1 | c.273C>T p.C91= | Silent (SNP) | VAF 117/284 reads (41%) | catalogued as COSV72649997; called by muse, varscan2
- ROBO4 | c.2496C>T p.S832= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs771809588, COSV100127812; called by mutect2, varscan2
- SGCD | c.840T>C p.T280= (on ENST00000435422 / NM_001128209.2; = p.T281= on NM_000337.5) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100551301; called by muse, mutect2, varscan2
- SIX6 | c.495C>T p.T165= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs758603385, COSV59803469; called by muse, mutect2, varscan2
- SLC4A11 | c.2376G>A p.A792= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs201769127, COSV101196143; called by muse, mutect2, varscan2
- SLC4A5 | c.1161C>T p.I387= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs377610601; called by muse, mutect2, varscan2
- SPTB | c.870C>T p.V290= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as rs781257002, COSV67634674; called by muse, mutect2, varscan2
- TLR8 | c.2736C>T p.N912= (on ENST00000218032 / NM_138636.5; = p.N930= on NM_016610.4) | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54318935, COSV54319234; called by muse, mutect2, varscan2
- TRIM7 | c.588C>T p.S196= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV99220582; called by muse, mutect2, varscan2
- USH2A | c.12702G>A p.T4234= | Silent (SNP) | VAF 206/377 reads (55%) | catalogued as rs878928366, COSV56424303; called by muse, mutect2, varscan2
- VCAN | c.9741C>T p.Y3247= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs374136117; called by muse, mutect2, varscan2
- ZFHX4 | c.4524T>C p.S1508= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV51491768; called by muse, mutect2, varscan2
- CCDC185 | c.-1G>A | 5'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs1053440884; called by muse, varscan2
- EI24P4 | n.1065C>T | RNA (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2
- MIR1-1HG-AS1 | n.575C>T | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as rs375083248; called by muse, mutect2, varscan2
- MIR516A1 | n.67C>G | RNA (SNP) | VAF 101/281 reads (36%) | called by muse, mutect2, varscan2
